Gene-level copy-number profile of tumor specimen TCGA-EE-A29G-06A from TCGA case TCGA-EE-A29G, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.1 years (21,596 days).
Specimen TCGA-EE-A29G-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.88b854e0-833f-43d6-8b94-9e4f6e60a7af.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A29G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00d7fe26-b10b-4a63-b00b-c7dcd3a45564

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 1,965; copy number 2: 21,063; copy number 3: 18,786; copy number 4: 10,878; copy number 5: 4,813; copy number 6: 1,178; copy number 7: 117; copy number 8: 565; copy number 9: 191; copy number 10: 100; copy number 11: 94; copy number 12: 3; copy number 13: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A29G-06A-12D-A194-01): tumor purity 0.21, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:160,121,815–163,578,592, 37 genes (within-gene range 0–3): SLC22A1, AL645733.1, SLC22A2, AL162582.1, SLC22A3, AL591069.1, LPAL2, LPA, AL109933.2, AL109933.1, PLG, AL109933.5, AL109933.4, AL109933.3, AL391361.2, AL391361.1, AL139393.2, AL139393.1, MAP3K4-AS1, MAP3K4, AGPAT4, PRKN, AL132982.1, AL138716.1, KRT8P44, PACRG, AL590286.1, AL590286.2, PACRG-AS2, AL137182.1, PACRG-AS3, PACRG-AS1, AL031121.2, AL031121.3, AL031121.1, CAHM, QKI.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,091 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:232,397,965–248,919,946, 384 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr4:40,423,267–40,630,875, 1 gene, copy number 6 (within-gene range 3–6): RBM47.
- chr4:40,502,040–57,855,271, 254 genes, copy number 6–8 (broad region; genes not listed).
- chr4:64,275,257–102,617,302, 571 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr4:104,900,125–106,453,449, 28 genes, copy number 9 (within-gene range 4–9): AC096577.1, RNU6-351P, AC096577.2, AC004069.2, AC004069.3, AC004069.1, TET2, TET2-AS1, RN7SL89P, PPA2, RNU6-553P, EEF1A1P9, PIMREGP2, ATP5F1EP1, AC004066.1, ARHGEF38, ARHGEF38-IT1, AC105391.1, INTS12, GSTCD, GSTCD-AS1, NPNT, AC109361.2, AC109361.1, TBCK, AIMP1, GIMD1, LINC02173.
- chr4:107,435,118–125,507,307, 248 genes, copy number 6–11 (broad region; genes not listed).
- chr4:128,768,228–147,684,163, 237 genes, copy number 6–12 (broad region; genes not listed).
- chr4:147,745,303–147,745,417, 1 gene, copy number 6: RNA5SP165.
- chr4:152,308,283–183,765,721, 391 genes, copy number 6–13 (broad region; genes not listed).
- chr4:184,584,093–190,092,279, 120 genes, copy number 7–9 (broad region; genes not listed).
- chr5:58,198–3,181,487, 87 genes, copy number 8–9 (broad region; genes not listed).
- chr6:167,607–37,699,306, 1,130 genes, copy number 5 (broad region; genes not listed).
- chr8:150,584–145,066,685, 2,481 genes, copy number 5 (broad region; genes not listed).
- chr13:93,226,807–94,408,020, 1 gene, copy number 5 (within-gene range 4–5): GPC6.
- chr13:93,818,424–114,337,626, 320 genes, copy number 5 (broad region; genes not listed).
- chr22:15,290,718–23,402,726, 480 genes, copy number 5 (broad region; genes not listed).
- chr22:26,161,834–27,920,134, 50 genes, copy number 5: LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1, ASPHD2, HPS4, SRRD, TFIP11, Z95115.1, TPST2, MIR548J, HMGB1P10, Z95115.2, CRYBB1, CRYBA4, ISCA2P1, MIAT, Z99774.5, Z99774.1, Z99774.4, Z99774.2, MIATNB, Z99774.3, LINC01422, Z97353.1, Z97353.2, AL008638.3, RNU6-1066P, AL008638.5, AL008638.4, AL008638.2, AL008638.6, AL008638.1, AL021153.1, LINC01638, AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1, AL050402.2, AL050402.1, AL133456.1, AL121885.2, AL121885.3, AL121885.1, MN1, PITPNB.
- chr22:27,919,384–27,922,178, 4 genes, copy number 5: AL031591.2, MIR3199-1, MIR3199-2, AL031591.1.
- chr22:38,032,165–47,487,111, 303 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,965. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
